Somatic mutation profile of tumor specimen TARGET-20-PASXAP-09A (aliquot TARGET-20-PASXAP-09A-01D) from TARGET case TARGET-20-PASXAP, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 11.5 years (4,191 days).
Specimen TARGET-20-PASXAP-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f8bd3528-9ca8-4764-b1c4-5350acfc556f.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PASXAP-14A (Bone Marrow Normal), aliquot TARGET-20-PASXAP-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/64c3503a-5a80-443f-b308-b5e35fe5ca9d

The open-access MAF lists 1 somatic variant for this specimen: 1 protein-altering or splice-affecting.
By variant classification: Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KIT | c.1252_1256del p.Y418Qfs*28 | Frame Shift Del (DEL) | VAF 109/242 reads (45%) | catalogued as COSV55393956; called by mutect2, pindel*, varscan2*
